Somatic mutation profile of tumor specimen TCGA-D7-A4YV-01A (aliquot TCGA-D7-A4YV-01A-11D-A25D-08) from TCGA case TCGA-D7-A4YV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.6 years (25,421 days).
Specimen TCGA-D7-A4YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2990db85-58fd-4cc5-a154-acea4ae105d0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-A4YV-10A (Blood Derived Normal), aliquot TCGA-D7-A4YV-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e844df61-c7d0-4fb7-bb05-5166a0db0d01

The open-access MAF lists 1,054 somatic variants for this specimen: 817 protein-altering or splice-affecting, 222 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 526, Silent 222, Frame Shift Del 191, Nonsense Mutation 41, Frame Shift Ins 31, Splice Site 13, Splice Region 8, In Frame Del 7, RNA 4, Intron 3, 3'Flank 3, 5'UTR 2.

Variants (750 of 1,054; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219del p.R74Gfs*23 | Frame Shift Del (DEL) | VAF 14/83 reads (17%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- BCHE | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745364489, CM034210, COSV52259719; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 33/221 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 28/88 reads (32%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- MBD5 | c.4455del p.K1486Nfs*55 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as rs1060501151; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MPV17 | c.262A>G p.K88E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs267607256, CM1010128, COSV51991356; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs886042002, CM162636, COSV55873442, COSV55926654, COSV55949642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.1692del p.K564Nfs*19 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs746427774; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA12 | c.1450G>A p.A484T (on ENST00000272895 / NM_173076.3; = p.A166T on NM_015657.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV55968297; called by muse, mutect2, varscan2
- ABCA2 | c.6410C>T p.T2137M (on ENST00000614293; = p.T2107M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs779450963, COSV55799178; called by muse, mutect2, varscan2
- ABCA4 | c.2491G>T p.G831W | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV64674978, COSV64675717; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA7 | c.5715C>T p.T1905= | Splice Region (SNP) | VAF 11/64 reads (17%) | catalogued as rs750505299, COSV54033714; called by muse, mutect2, varscan2
- ABCA8 | c.898A>G p.M300V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs747505203, COSV52207487; called by muse, mutect2, varscan2
- ABCA9 | c.348A>T p.E116D | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV60628469; called by muse, mutect2, varscan2
- AC109583.1 | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 44/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143437619, COSV58406191; called by muse, mutect2, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 19/122 reads (16%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACP4 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141753566, COSV99567672; called by muse, mutect2, varscan2
- ACSS1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs112767555, COSV60218119; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 54/113 reads (48%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs1562667957, COSV52038954; called by muse, mutect2, varscan2
- ADCY2 | c.2432C>A p.S811Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV57859892; called by muse, varscan2
- ADCY6 | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57169403; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57076449; called by muse, mutect2, varscan2
- ADGRE2 | c.870A>C p.R290S | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV59695120; called by muse, mutect2, varscan2
- ADGRG4 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54962308, COSV54970547; called by muse, mutect2, varscan2
- ADSL | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV50653911; called by muse, mutect2, varscan2
- AGFG2 | c.752-1G>A p.X251_splice | Splice Site (SNP) | VAF 57/205 reads (28%) | catalogued as rs1189404193, COSV53546324; called by muse, mutect2, varscan2
- AGTPBP1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.291); catalogued as rs1433230227, COSV61274122; called by muse, mutect2, varscan2
- AHNAK | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276199931, COSV57222700; called by muse, mutect2, varscan2
- AHRR | c.63-1G>A p.X21_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as rs111551936, COSV57090488; called by muse, mutect2, varscan2
- AKAP17A | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); catalogued as COSV58311064; called by muse, mutect2, varscan2
- AKR1B10 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV62056093, COSV62056274; called by muse, mutect2, varscan2
- AL645922.1 | c.3481_3482del p.D1161Cfs*8 | Frame Shift Del (DEL) | VAF 18/112 reads (16%) | catalogued as rs772068606; called by pindel, varscan2
- ALPK1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs753593541, COSV51588703; called by muse, mutect2, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel, varscan2
- AMZ1 | c.791G>A p.C264Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1159033628, COSV56688259; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKK1 | c.1552del p.A518Lfs*10 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs1272691654; called by mutect2, varscan2
- ANKRD13B | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1417417757, COSV61471570; called by muse, mutect2, varscan2
- ANKRD34B | c.1247del p.P416Qfs*4 | Frame Shift Del (DEL) | VAF 39/156 reads (25%) | catalogued as rs779065930, COSV100103683; called by mutect2, pindel, varscan2
- ANLN | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs564754015, COSV56076129; called by muse, mutect2, varscan2
- ANO9 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60384514; called by muse, mutect2, varscan2
- ANOS1 | c.1842C>T p.S614= | Splice Region (SNP) | VAF 11/45 reads (24%) | catalogued as rs750983454, COSV52923501; called by muse, mutect2, varscan2
- ANXA13 | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as rs779057517, COSV51622959; called by muse, mutect2, varscan2
- AP1G1 | c.1880A>T p.D627V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV55489110, COSV55492909; called by muse, mutect2, varscan2
- AP4E1 | c.1586C>T p.T529M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs200110517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as rs757164742, CD971991, COSV57330445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOBEC3G | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.217); catalogued as COSV68470574; called by muse, mutect2, varscan2
- AQR | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs749141492, COSV50042770; called by muse, mutect2, varscan2
- ARAF | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.225); catalogued as rs199527940, COSV51691535; called by muse, mutect2
- ARHGAP21 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV100255867; called by mutect2, varscan2
- ARHGEF10 | c.3398G>A p.R1133H (on ENST00000398564; = p.R1108H on NM_014629.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as rs779333941, COSV50662954; called by muse, mutect2, varscan2
- ARHGEF25 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 129/324 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs200472423, COSV54085264; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 48/140 reads (34%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARID2 | c.3065del p.P1022Hfs*38 | Frame Shift Del (DEL) | VAF 10/83 reads (12%) | catalogued as COSV57596937; called by mutect2, pindel, varscan2
- ARNT | c.2358del p.S788Qfs*21 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as rs745521026; called by mutect2, pindel, varscan2
- ARSJ | c.591del p.F197Lfs*54 | Frame Shift Del (DEL) | VAF 50/180 reads (28%) | catalogued as rs1269648295; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ARVCF | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767223253, COSV54269466, COSV54269627; called by mutect2, varscan2
- ASB15 | c.1006A>G p.T336A | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51927907; called by muse, varscan2
- ASPH | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371485848; called by muse, mutect2, varscan2
- ASTN2 | c.2521+1G>A p.X841_splice (on ENST00000313400 / NM_001365069.1; = p.X790_splice on NM_014010.5) | Splice Site (SNP) | VAF 62/309 reads (20%) | catalogued as COSV57799547; called by muse, mutect2, varscan2
- ATP2A1 | c.1712del p.P571Rfs*21 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | catalogued as rs772363145; called by mutect2, pindel, varscan2
- ATP4A | c.2425G>A p.V809M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as rs778443222, COSV52870083; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1280A>C p.Q427P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV52270696; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868258923, COSV52352759; called by muse, mutect2, varscan2
- ATRX | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64880418; called by muse, mutect2, varscan2
- ATXN10 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as rs1042452273, COSV53298989, COSV99426550; called by muse, mutect2, varscan2
- B3GNT4 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs769085783, COSV57336999; called by muse, mutect2, varscan2
- BACH1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.469); catalogued as rs773339742, COSV54520052; called by muse, mutect2, varscan2
- BARX1 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54158723; called by muse, mutect2, varscan2
- BAZ2B | c.4841C>T p.P1614L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV58605965; called by muse, mutect2, varscan2
- BCHE | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV52254580, COSV52259710; called by muse, mutect2, varscan2
- BCL11A | c.1415C>T p.T472M (on ENST00000335712 / NM_001365609.1; = p.T506M on NM_018014.4) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.482); catalogued as rs919252266, COSV59633959; called by muse, mutect2
- BCL11B | c.1891G>A p.G631R (on ENST00000357195 / NM_001282237.2; = p.G560R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as COSV61737557; called by muse, mutect2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs751794665; called by mutect2, varscan2
- BDH1 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV64019208; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs752427670; called by mutect2, varscan2
- BIN1 | c.273G>T p.E91D | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV52120409; called by muse, mutect2, varscan2
- BMP5 | c.1211C>T p.T404I | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63705018; called by muse, mutect2, varscan2
- BMP6 | c.527del p.P176Rfs*25 | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as rs1271732710; called by mutect2, varscan2
- BOC | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780959946, COSV56355042; called by muse, mutect2, varscan2
- BOD1L1 | c.7639G>A p.A2547T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV50031278; called by muse, mutect2
- BRIP1 | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs578022079, COSV51997487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSN | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs572736678, COSV56523448; called by muse, mutect2, varscan2
- BTBD11 | c.2011G>C p.D671H (on ENST00000280758 / NM_001018072.2; = p.D208H on NM_001017523.2) | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55031246; called by muse, mutect2, varscan2
- BTBD8 | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV61547194; called by muse, mutect2, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C1QL2 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV55607167; called by muse, mutect2, varscan2
- CACNA1E | c.1000C>A p.L334I | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62407551; called by muse, mutect2
- CACNA1F | c.4183G>A p.G1395R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370863603, COSV100544816, COSV59905779; called by muse, mutect2, varscan2
- CADM1 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); catalogued as rs1235105339, COSV59017162; called by muse, mutect2, varscan2
- CAPN15 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1426542744, COSV54838144; called by muse, mutect2, varscan2
- CARD14 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370897817; called by muse, mutect2, varscan2
- CASKIN1 | c.2423del p.P808Rfs*76 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV100398950, COSV100399475; called by mutect2, varscan2
- CCDC126 | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56740704; called by muse, mutect2, varscan2
- CCDC178 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779422806, COSV55761954; called by muse, mutect2, varscan2
- CCDC80 | c.1658del p.K553Rfs*2 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1253078189; called by mutect2, varscan2
- CCER1 | c.265G>T p.G89* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62647849; called by muse, mutect2, varscan2
- CCN3 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 48/295 reads (16%) | catalogued as rs762578372, COSV52384647; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 23/138 reads (17%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD6 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.908); catalogued as rs1400464678; called by muse, mutect2
- CD93 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs761695801, COSV55663392; called by muse, mutect2, varscan2
- CDC42EP1 | c.289del p.R97Gfs*115 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | catalogued as rs762035931; called by mutect2, pindel, varscan2
- CDH10 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52589426; called by muse, mutect2, varscan2
- CDH15 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as rs758601065, COSV57025986; called by muse, mutect2, varscan2
- CDH23 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs370549448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDYL2 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV73647763; called by muse, mutect2, varscan2
- CEACAM16 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.005); catalogued as rs756280582, COSV69187630; called by muse, mutect2
- CEACAM16 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as COSV69186352; called by muse, mutect2, varscan2
- CEACAM20 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.218); catalogued as COSV57602533; called by muse, mutect2, varscan2
- CENPU | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.139); catalogued as COSV99859773; called by muse, mutect2, varscan2
- CEP164 | c.2274G>T p.E758D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54043969; called by muse, mutect2
- CFAP74 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 21/85 reads (25%) | catalogued as COSV54570752; called by muse, mutect2, varscan2
- CGRRF1 | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53597589; called by muse, mutect2, varscan2
- CHD4 | c.1936G>A p.V646M (on ENST00000357008 / NM_001363606.2; = p.V659M on NM_001273.5) | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58906750; called by muse, mutect2
- CHGB | c.630del p.E211Rfs*3 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | catalogued as rs1568551915; called by pindel, varscan2
- CHST1 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 27/118 reads (23%) | catalogued as COSV57324731; called by muse, mutect2, varscan2
- CHST7 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.151); catalogued as COSV52100629; called by muse, mutect2
- CHST7 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV52100728; called by muse, mutect2, varscan2
- CHST9 | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV52432774, COSV52444115; called by muse, mutect2, varscan2
- CHSY3 | c.866C>G p.T289S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV59282592; called by muse, mutect2, varscan2
- CLASP2 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56288803; called by muse, mutect2, varscan2
- CLCA4 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs748985367, COSV55368285, COSV55369779; called by muse, mutect2, varscan2
- CLCNKB | c.1395del p.Y466Mfs*13 | Frame Shift Del (DEL) | VAF 28/119 reads (24%) | catalogued as rs762878606; called by mutect2, pindel, varscan2
- CLDN12 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761164855, COSV55307513, COSV55307690; called by muse, mutect2, varscan2
- CLDN20 | c.144del p.H48Qfs*19 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | catalogued as COSV65697308; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 38/117 reads (32%) | catalogued as rs369752219; called by mutect2, varscan2
- CNGA4 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs773908561, COSV66005104; called by muse, mutect2, varscan2
- CNTLN | c.3142C>T p.R1048W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs200093382; called by muse, mutect2, varscan2
- CNTNAP1 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV52848778; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COIL | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV53595863; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | catalogued as rs748995811; called by mutect2, varscan2
- COL5A3 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.307); catalogued as rs774594724, COSV53406624, COSV53414403; called by muse, mutect2, varscan2
- COL6A3 | c.4679C>A p.A1560D | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs1045952953, COSV55099666; called by muse, mutect2, varscan2
- COL6A6 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs774968132, COSV62031843; called by muse, mutect2, varscan2
- COL6A6 | c.5686G>A p.V1896M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1198774233, COSV62031861; called by muse, mutect2
- COLGALT1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs142308296; called by muse, mutect2, varscan2
- CORO1B | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as rs761036671, COSV57052772; called by muse, mutect2, varscan2
- CPA4 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 18/74 reads (24%) | catalogued as rs372059567, COSV55984525; called by muse, mutect2, varscan2
- CPNE6 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1309611295, COSV53742777; called by muse, mutect2, varscan2
- CRACR2A | c.950G>T p.R317L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV52916016; called by muse, mutect2, varscan2
- CREB3L1 | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs559259997, COSV55830395; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG3 | c.5926G>A p.E1976K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV51714298; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSK | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs144688425; called by muse, mutect2, varscan2
- CSMD2 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750496961, COSV53899208; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 14/102 reads (14%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CST4 | c.241del p.V81* | Frame Shift Del (DEL) | VAF 49/298 reads (16%) | catalogued as rs767756120; called by mutect2, pindel, varscan2
- CTNNA1 | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as rs1294176302, COSV57069858; called by muse, mutect2, varscan2
- CTSH | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs377571418; called by muse, mutect2, varscan2
- CUX1 | c.2446C>T p.R816C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1458129301, COSV52902290, COSV52907923; called by muse, mutect2, varscan2
- CYFIP1 | c.3100C>T p.R1034* | Nonsense Mutation (SNP) | VAF 35/162 reads (22%) | catalogued as rs1404007149, COSV57413066; called by muse, mutect2, varscan2
- CYREN | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as COSV51966713; called by muse, mutect2, varscan2
- DARS1 | c.1230+1G>A p.X410_splice | Splice Site (SNP) | VAF 32/110 reads (29%) | catalogued as rs747031340, COSV51540186; called by muse, mutect2, varscan2
- DAXX | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 36/167 reads (22%) | catalogued as rs779014832, COSV56468939; called by muse, mutect2, varscan2
- DCAF4L2 | c.704T>C p.M235T | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV60480546; called by muse, mutect2, varscan2
- DCAF5 | c.2653G>A p.G885R | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.178); catalogued as rs766102697, COSV58461766; called by muse, mutect2, varscan2
- DCHS1 | c.4768G>A p.G1590S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs934539374, COSV55033450; called by muse, mutect2, varscan2
- DCUN1D1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs1451035070, COSV53045527; called by muse, mutect2, varscan2
- DDIT3 | c.195G>T p.E65D | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV56257178; called by muse, mutect2, varscan2
- DDX39A | c.618G>A p.M206I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV54392582; called by muse, mutect2, varscan2
- DGKK | c.1178A>T p.D393V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1557226884, COSV65708733; called by muse, mutect2, varscan2
- DHX35 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 124/731 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755282012, COSV52672386; called by muse, mutect2, varscan2
- DIAPH3 | c.960del p.I320Mfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Mfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | catalogued as rs751708891; called by mutect2, pindel, varscan2
- DLL1 | c.845dup p.L283Pfs*14 | Frame Shift Ins (INS) | VAF 17/78 reads (22%) | catalogued as rs760008381; called by mutect2, varscan2
- DMAC2L | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765011759, COSV55413927; called by muse, mutect2, varscan2
- DMD | c.6319C>T p.R2107W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as rs770711808, COSV63772206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNA2 | c.1399A>G p.M467V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64429385; called by muse, mutect2
- DNAJB13 | c.475del p.I159Lfs*8 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | catalogued as rs754363435; called by mutect2, pindel, varscan2
- DNAJB14 | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV62034733; called by muse, mutect2, varscan2
- DNAJC6 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755390221, COSV54778792; called by muse, mutect2, varscan2
- DNM2 | c.2399C>T p.A800V (on ENST00000355667 / NM_001005360.3; = p.A796V on NM_004945.3) | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs1050140753, COSV53034726; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.67del p.L23Cfs*25 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | catalogued as rs751315109; called by mutect2, varscan2
- DOP1A | c.3092G>A p.S1031N | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV52714239; called by muse, mutect2, varscan2
- DOP1B | c.3721C>T p.L1241F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281284727, COSV101215021, COSV67694624; called by muse, mutect2, varscan2
- DPP6 | c.1205C>T p.A402V (on ENST00000377770 / NM_001364500.2; = p.A340V on NM_001936.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV100123048, COSV59631831; called by muse, mutect2
- DPP6 | c.1654C>T p.L552F (on ENST00000377770 / NM_001364500.2; = p.L490F on NM_001936.5) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59631856; called by muse, mutect2, varscan2
- DST | c.8094T>A p.N2698K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV99752190; called by muse, mutect2
- DUSP5 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs755076416, COSV63646744; called by muse, mutect2
- DYRK4 | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV50542142; called by muse, mutect2, varscan2
- EDA | c.504C>T p.G168= | Splice Region (SNP) | VAF 11/49 reads (22%) | catalogued as COSV65782887; called by muse, mutect2, varscan2
- EDN3 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM101978, COSV61109096; called by muse, mutect2, varscan2
- EHD1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as rs768139342, COSV57735746, COSV57736284; called by muse, mutect2, varscan2
- EHD2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as rs745870470, COSV54409849; called by muse, mutect2, varscan2
- EIF1AX | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV63309411; called by muse, mutect2, varscan2
- ELL3 | c.759A>C p.E253D | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.592); catalogued as COSV55857406; called by muse, mutect2, varscan2
- ELP1 | c.607dup p.D203Gfs*33 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as rs752490541; called by mutect2, pindel, varscan2
- EMILIN3 | c.2227G>C p.A743P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV60037567; called by muse, mutect2, varscan2
- ENOSF1 | c.1069C>T p.Q357* (on ENST00000340116 / NM_001354066.2; = p.Q323* on NM_017512.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | catalogued as rs1439260586, COSV51894251; called by mutect2, varscan2
- EP400 | c.8456C>A p.P2819Q | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV57763173, COSV57779591; called by muse, mutect2
- EP400 | c.8746G>A p.A2916T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.461); catalogued as COSV57779604; called by muse, mutect2
- EPHA4 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as COSV56039217; called by muse, mutect2, varscan2
- EPHA5 | c.3097G>A p.G1033R | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.106); catalogued as rs139793674; called by muse, mutect2, varscan2
- EPHB1 | c.2666A>C p.K889T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67666489; called by muse, mutect2
- ERAS | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV54433176; called by muse, mutect2, varscan2
- ETV7 | c.529C>A p.P177T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV60317934; called by muse, mutect2
- EVC | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs777256784, COSV53835800; called by muse, mutect2, varscan2
- EVPL | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.978); catalogued as COSV56913666; called by muse, mutect2, varscan2
- EXD3 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765802505, COSV59805172; called by muse, mutect2, varscan2
- EXOC3L1 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as rs762740345, COSV52047597; called by muse, mutect2, varscan2
- EXOC3L4 | c.1584G>A p.P528= | Splice Region (SNP) | VAF 15/82 reads (18%) | catalogued as rs374105891, COSV66295780; called by muse, mutect2, varscan2
- EYS | c.1654T>C p.Y552H | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV60993872; called by muse, mutect2, varscan2
- F11 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV53002632; called by muse, mutect2, varscan2
- FAM107B | c.418_420del p.E140del | In Frame Del (DEL) | VAF 27/121 reads (22%) | catalogued as rs1051396277; called by pindel, varscan2
- FAM160A2 | c.1606C>T p.R536* (on ENST00000449352 / NM_001098794.2; = p.R550* on NM_032127.4) | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as rs1441035616, COSV56413193; called by muse, mutect2, varscan2
- FAM47B | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.167); catalogued as COSV61454741, COSV61455586; called by muse, mutect2
- FAM91A1 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV58238353; called by muse, mutect2, varscan2
- FAM9C | c.329+2T>C p.X110_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV61775796; called by muse, mutect2
- FARSA | c.437del p.G146Dfs*14 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as rs746493788; called by mutect2, pindel, varscan2
- FASN | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs143812680; called by muse, mutect2, varscan2
- FASTKD1 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs767676718, COSV71624558; called by muse, mutect2, varscan2
- FAT1 | c.12877C>T p.H4293Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.629); catalogued as COSV71675210; called by muse, mutect2, varscan2
- FAT1 | c.3443T>C p.I1148T | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV71675211; called by muse, mutect2, varscan2
- FBN3 | c.2259del p.G754Afs*23 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as COSV54456788; called by mutect2, pindel, varscan2
- FBXO38 | c.3011G>A p.R1004H (on ENST00000340253 / NM_205836.3; = p.R929H on NM_030793.5) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1273134578, COSV57027109; called by muse, mutect2, varscan2
- FCGR2A | c.859G>A p.G287S (on ENST00000271450 / NM_001136219.3; = p.G286S on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.757); catalogued as rs376020188; called by muse, mutect2, varscan2
- FCRL3 | c.1175C>G p.A392G | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV100943546, COSV63843555; called by muse, mutect2, varscan2
- FEM1B | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.756); catalogued as rs780106358, COSV60989135; called by muse, mutect2, varscan2
- FER1L5 | c.5123A>G p.Y1708C (on ENST00000623019; = p.Y1681C on NM_001293083.2) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV67606630; called by muse, mutect2, varscan2
- FGF21 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55810846; called by muse, mutect2, varscan2
- FGL1 | c.816C>A p.S272R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs771078136, COSV67713036; called by mutect2, varscan2
- FLNC | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs758342140, COSV57954318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.2509A>C p.M837L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54062124; called by muse, mutect2, varscan2
- FLVCR2 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs772508772, COSV53163538; called by muse, mutect2, varscan2
- FNIP2 | c.1804C>A p.P602T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.242); catalogued as COSV52443151; called by muse, mutect2, varscan2
- FOXN1 | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV56883080; called by muse, mutect2, varscan2
- FOXN3 | c.287del p.P96Hfs*42 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | catalogued as rs760347049; called by mutect2, pindel, varscan2
- FPR2 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs778561198, COSV60673907; called by muse, mutect2, varscan2
- FUT1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs1253586923, COSV59569366, COSV59569695; called by muse, mutect2, varscan2
- FUT9 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs142793962, COSV56143987, COSV56150338; called by muse, mutect2, varscan2
- FYN | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs1298055854, COSV57617817; called by muse, mutect2, varscan2
- FZD10 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV57473678, COSV99969588; called by mutect2, varscan2
- FZD5 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.17); catalogued as COSV54944091; called by muse, mutect2
- FZD5 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54944103; called by muse, mutect2, varscan2
- GABRB3 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV54674896; called by muse, mutect2, varscan2
- GAK | c.3025G>A p.A1009T | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs140672161; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs758551787; called by mutect2, varscan2
- GAS6 | c.449del p.G150Afs*49 | Frame Shift Del (DEL) | VAF 26/161 reads (16%) | catalogued as rs773341392; called by mutect2, pindel, varscan2
- GDAP1 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55185036; called by muse, mutect2, varscan2
- GDAP1L1 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755646369, COSV61158174; called by muse, mutect2, varscan2
- GDF11 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1381538589, COSV57690303; called by muse, mutect2, varscan2
- GDPD3 | c.183C>T p.N61= | Splice Region (SNP) | VAF 17/76 reads (22%) | catalogued as rs1271958580, COSV53775330; called by muse, mutect2, varscan2
- GGN | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.084); catalogued as rs1022271635, COSV53057377; called by muse, mutect2, varscan2
- GIGYF1 | c.331del p.L111Wfs*234 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs763147690; called by mutect2, varscan2
- GIMAP8 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs200592029, COSV56232852, COSV56235726; called by muse, mutect2, varscan2
- GK2 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV62627797; called by muse, mutect2, varscan2
- GLB1L3 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376238782, COSV68393070; called by muse, mutect2, varscan2
- GLS | c.1656G>T p.K552N | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV57844128; called by muse, mutect2, varscan2
- GLYATL2 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen possibly damaging (0.524); catalogued as rs200152129, COSV54850827; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs749150409; called by mutect2, varscan2
- GMPPA | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754071645, COSV58006109, COSV58008432; called by muse, mutect2, varscan2
- GNAQ | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV54120049; called by muse, mutect2, varscan2
- GPR101 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV53239711; called by muse, mutect2
- GPR135 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201546415, COSV67749742; called by muse, mutect2, varscan2
- GRIN2A | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1354238435, COSV58046734; called by muse, mutect2, varscan2
- GTF3C1 | c.3656G>A p.R1219Q | Missense Mutation (SNP) | VAF 51/225 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs201935197, COSV62243141; called by muse, mutect2, varscan2
- GTF3C2 | c.653T>C p.V218A | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs575336288, COSV53127941; called by muse, mutect2, varscan2
- GTF3C3 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as rs1243371042, COSV55833469; called by muse, mutect2, varscan2
- GTF3C5 | c.929del p.N310Tfs*18 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | catalogued as rs1413670724; called by mutect2, varscan2
- GUSB | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as rs769769379, COSV59222769; called by muse, mutect2
- GZMH | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 63/252 reads (25%) | catalogued as COSV53539020; called by muse, mutect2, varscan2
- H2BC1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs765867752, COSV51237847; called by muse, mutect2, varscan2
- HACD1 | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs140078758, COSV63516818; called by muse, mutect2, varscan2
- HEATR1 | c.1330T>A p.L444I | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV63982258; called by muse, mutect2, varscan2
- HEATR5B | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV51856072; called by muse, mutect2, varscan2
- HECTD4 | c.7762G>A p.A2588T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV66396160; called by muse, mutect2, varscan2
- HECTD4 | c.6029C>T p.A2010V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66396164; called by muse, mutect2, varscan2
- HELZ2 | c.2689G>A p.V897M (on ENST00000467148 / NM_001037335.2; = p.V328M on NM_033405.3) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1316631723, COSV64410134; called by muse, mutect2
- HFM1 | c.2866del p.I956* | Frame Shift Del (DEL) | VAF 34/120 reads (28%) | catalogued as rs1180713834; called by mutect2, pindel, varscan2
- HIVEP3 | c.5039C>T p.S1680F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56019502, COSV99911642; called by muse, mutect2, varscan2
- HJV | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60952774; called by muse, mutect2, varscan2
- HMCN1 | c.7328G>A p.R2443Q | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs533111130, COSV54921083; called by muse, mutect2, varscan2
- HMCN1 | c.13346C>T p.T4449I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs758752400, COSV54921097; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs761272507; called by mutect2, varscan2
- HMX3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63501901; called by muse, varscan2
- HNRNPH1 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.597); catalogued as rs1461534520, COSV100270246, COSV61487520; called by muse, mutect2, varscan2
- HOMEZ | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 52/195 reads (27%) | catalogued as rs776204768, COSV62537517; called by muse, mutect2, varscan2
- HOXD10 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs779016325, COSV50893286, COSV50893495; called by muse, mutect2, varscan2
- HPS6 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV54626239; called by muse, mutect2
- HRH4 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV56929020; called by muse, mutect2, varscan2
- HS3ST3A1 | c.607A>C p.M203L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV52377312; called by muse, mutect2, varscan2
- HSPA8 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV57085048; called by muse, mutect2, varscan2
- HTRA4 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs747418954, COSV56760339; called by muse, mutect2, varscan2
- IGDCC3 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs759024595, COSV60078817; called by muse, varscan2
- IGHA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782085693; called by muse, mutect2, varscan2
- IGHD | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.439); catalogued as COSV101162813; called by muse, mutect2, varscan2
- IGHE | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs368118853; called by muse, mutect2, varscan2
- IGSF9 | c.1804G>T p.A602S (on ENST00000368094 / NM_001135050.2; = p.A586S on NM_020789.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV63641106; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1699T>G p.C567G | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV61169389, COSV61188019; called by muse, mutect2, varscan2
- IL21R | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs149169230; called by muse, mutect2, varscan2
- ILKAP | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs142248095; called by muse, mutect2, varscan2
- INKA1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs766185057, COSV58526328; called by muse, mutect2, varscan2
- INSM2 | c.1605dup p.S536* | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs756928018; called by mutect2, varscan2
- INTS2 | c.2615del p.P872Hfs*2 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs753355779, COSV52155455; called by mutect2, pindel, varscan2
- INTS5 | c.2740A>G p.M914V | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV57952711; called by muse, mutect2, varscan2
- IP6K1 | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57696139; called by muse, mutect2, varscan2
- IPO4 | c.2563T>G p.F855V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV61017547; called by muse, mutect2
- IQSEC2 | c.848G>C p.G283A (on ENST00000642864 / NM_001111125.3; = p.G78A on NM_015075.2) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.015); catalogued as rs1241595562, COSV64726734; ClinVar: uncertain significance; called by muse, mutect2
- IRGC | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs1388905075, COSV54984510; called by muse, mutect2, varscan2
- ISOC2 | c.353C>T p.T118M (on ENST00000425675 / NM_001136201.2; = p.T134M on NM_024710.3) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs574543639, COSV50035216; called by muse, varscan2
- ITFG1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV54518528, COSV54528411; called by muse, mutect2, varscan2
- ITGAD | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV66759042; called by muse, mutect2, varscan2
- ITPR1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV56994203; called by muse, mutect2, varscan2
- ITPR1 | c.5752G>A p.E1918K (on ENST00000354582; = p.E1863K on NM_002222.7) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.358); catalogued as COSV56994233; called by muse, mutect2
- ITPRID1 | c.1954T>C p.Y652H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV60078847; called by muse, mutect2
- IVL | c.128del p.P43Hfs*22 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | catalogued as COSV64216943; called by mutect2, pindel, varscan2
- JAKMIP2 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV54610346; called by muse, mutect2, varscan2
- JPH2 | c.415C>A p.H139N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV65904705; called by muse, varscan2
- KBTBD12 | c.1835del p.P612Rfs*78 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | catalogued as rs1187501286, COSV100675484; called by mutect2, pindel, varscan2
- KCNA6 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54974391; called by muse, mutect2, varscan2
- KCNJ4 | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV57857954; called by muse, mutect2, varscan2
- KCNK13 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1051052235, COSV56415219; called by muse, mutect2, varscan2
- KCNN2 | c.1669C>T p.R557W (on ENST00000264773; = p.R769W on NM_021614.4) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs930725873, COSV53289916, COSV53295542; called by muse, mutect2, varscan2
- KIF1A | c.2437C>T p.R813W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328033713, COSV57493854; called by muse, mutect2, varscan2
- KIF3C | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV53100835; called by muse, mutect2, varscan2
- KIFC2 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56762116; called by muse, mutect2, varscan2
- KIN | c.505del p.T169Lfs*9 | Frame Shift Del (DEL) | VAF 84/327 reads (26%) | catalogued as rs769387138, COSV65430366; called by mutect2, pindel, varscan2
- KLHL24 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs773448712, COSV54426935; called by muse, mutect2, varscan2
- KLHL36 | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs140616787, COSV50721302; called by muse, mutect2, varscan2
- KMT2D | c.7169del p.P2390Rfs*36 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as COSV56432484; called by mutect2, pindel, varscan2
- KNDC1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.197); catalogued as rs754002499, COSV58832646, COSV58834146; called by muse, mutect2, varscan2
- KRT23 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs758942765, COSV52927073, COSV52928549; called by muse, mutect2, varscan2
- KRT72 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs781275788, COSV53375363, COSV53375470; called by muse, mutect2, varscan2
- KRTAP5-1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.099); catalogued as rs145180041; called by muse, mutect2, varscan2
- LAD1 | c.1519C>T p.Q507* | Nonsense Mutation (SNP) | VAF 29/162 reads (18%) | catalogued as COSV66212962; called by muse, mutect2
- LAMA1 | c.620G>A p.S207N | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67540621; called by muse, mutect2, varscan2
- LAMP3 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV55615901; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs775423572; called by mutect2, pindel, varscan2
- LINGO4 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.362); catalogued as rs142939659; called by muse, mutect2, varscan2
- LMF1 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as rs369478194; called by muse, mutect2, varscan2
- LMTK2 | c.3473G>A p.S1158N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52000103; called by muse, mutect2, varscan2
- LPIN3 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754995106, COSV64719537; called by muse, mutect2, varscan2
- LRCH2 | c.1676T>G p.I559S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV57755694; called by muse, mutect2, varscan2
- LRP12 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs770819286, COSV52626191; called by muse, mutect2, varscan2
- LRP4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.136); catalogued as COSV66137387; called by muse, mutect2, varscan2
- LRRC37A3 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as rs1317783399, COSV59762661; called by muse, mutect2, varscan2
- LRRC37B | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.637); catalogued as COSV100496076; called by muse, mutect2
- LRRIQ1 | c.1470del p.K490Nfs*28 | Frame Shift Del (DEL) | VAF 12/76 reads (16%) | catalogued as COSV101280733; called by mutect2, pindel, varscan2
- LRRIQ3 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV63047494; called by muse, mutect2, varscan2
- LTBP3 | c.2874_2875insA p.C959Mfs*35 | Frame Shift Ins (INS) | VAF 9/48 reads (19%) | catalogued as COSV99533850; called by mutect2, pindel, varscan2
- MAGEA6 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 68/267 reads (25%) | catalogued as COSV61449059; called by muse, mutect2, varscan2
- MAGEB1 | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66776186; called by muse, mutect2, varscan2
- MAGT1 | c.25T>C p.C9R (on ENST00000618282 / NM_001367916.1; = p.C41R on NM_032121.5) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63782526; called by muse, mutect2, varscan2
- MAN2A2 | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as rs562419236, COSV64639187; called by muse, mutect2, varscan2
- MAP3K10 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763193956, COSV53422850; called by muse, mutect2, varscan2
- MAP3K4 | c.3758C>A p.P1253H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815057, COSV62336244; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51723923; called by muse, mutect2, varscan2
- MAPKAP1 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs377752331; called by muse, mutect2, varscan2
- MBNL2 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1300870013, COSV59119344; called by muse, mutect2, varscan2
- MBOAT1 | c.368T>G p.I123S | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV61126701; called by muse, mutect2, varscan2
- MDC1 | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64524387, COSV64525948; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs1180255648; called by mutect2, pindel
- MEGF10 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57253462; called by muse, mutect2, varscan2
- MELTF | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs549039602, COSV56383273; called by muse, mutect2, varscan2
- MFSD13A | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1187128630, COSV53268479, COSV99488011; called by muse, mutect2, varscan2
- MGAM | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as rs368879552, COSV101516582; called by muse, mutect2, varscan2
- MGAT5 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259347614, COSV56099013; called by muse, varscan2
- MICAL2 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV56323256; called by muse, mutect2, varscan2
- MICB | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.877); catalogued as rs757078199, COSV52857218; called by muse, mutect2, varscan2
- MIPEP | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as COSV66299785, COSV66301026; called by muse, mutect2, varscan2
- MIPOL1 | c.1132T>A p.S378T | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as COSV59388801; called by muse, mutect2, varscan2
- MKI67 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.058); catalogued as rs199572304; called by muse, mutect2, varscan2
- MLIP | c.459del p.I154Lfs*11 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | catalogued as rs767692253; called by mutect2, pindel, varscan2
- MMAB | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs768176676, CM153583, COSV57169638, COSV57170786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP15 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54680646; called by muse, mutect2, varscan2
- MMP8 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV52633670; called by muse, mutect2, varscan2
- MNDA | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV63741611; called by muse, mutect2, varscan2
- MRC1 | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as rs922406253; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MREG | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV54374987; called by muse, mutect2
- MRM3 | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58680244; called by muse, mutect2, varscan2
- MTA3 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV63196940; called by muse, mutect2, varscan2
- MTMR8 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV66395300; called by muse, mutect2, varscan2
- MTUS1 | c.1007del p.N336Ifs*2 | Frame Shift Del (DEL) | VAF 34/190 reads (18%) | catalogued as COSV50554380; called by mutect2, pindel, varscan2
- MUC17 | c.10268C>A p.P3423H | Missense Mutation (SNP) | VAF 25/400 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60296582; called by muse, mutect2
- MUS81 | c.1273-2A>G p.X425_splice | Splice Site (SNP) | VAF 27/116 reads (23%) | catalogued as COSV57260939; called by muse, mutect2, varscan2
- MXRA5 | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs193920874, COSV54230682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH13 | c.1378G>A p.G460R | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs768240121, COSV52830987; called by muse, mutect2, varscan2
- MYH2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs183147747, COSV55443582; called by muse, mutect2, varscan2
- MYH3 | c.4841G>A p.R1614Q | Missense Mutation (SNP) | VAF 105/420 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs750163741, COSV56867826; called by muse, mutect2, varscan2
- MYO15A | c.5197C>T p.R1733W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs369755064, COSV52761330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.5023C>T p.H1675Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV68281306; called by muse, mutect2, varscan2
- MZF1 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV53042366; called by muse, mutect2, varscan2
- NACC2 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1382630533; called by muse, mutect2, varscan2
- NALCN | c.3649G>A p.A1217T | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); catalogued as COSV51951573; called by muse, mutect2, varscan2
- NAV2 | c.4999+2T>C p.X1667_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV60662371; called by muse, mutect2, varscan2
- NCAM1 | c.902A>G p.H301R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV57520864; called by muse, mutect2
- NCOR1 | c.2171A>T p.E724V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51986071; called by muse, mutect2, varscan2
- NDUFB3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs373095347; called by muse, mutect2, varscan2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs747914168; called by mutect2, varscan2
- NEBL | c.2401G>A p.V801M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); catalogued as rs772136984, COSV65804614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NES | c.4301C>A p.A1434D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV63961953; called by muse, mutect2, varscan2
- NFKB2 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs759429094, COSV50051478; called by muse, mutect2, varscan2
- NLRP12 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.291); catalogued as COSV60751137; called by muse, mutect2, varscan2
- NOL6 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753538678, COSV53041015; called by muse, mutect2, varscan2
- NOP58 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as rs763440974, COSV51897778; called by muse, mutect2, varscan2
- NOTCH1 | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756087913, COSV53049883; ClinVar: uncertain significance; called by muse, mutect2
- NOTCH2 | c.2379G>T p.Q793H | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV56698685; called by muse, mutect2, varscan2
- NOX5 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs373906925, COSV52992960, COSV52997061; called by muse, mutect2, varscan2
- NPC1 | c.3560C>T p.A1187V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs113371321, CM096666, CM162520, COSV52573233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPSR1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs766192701, COSV62196325; called by muse, mutect2, varscan2
- NPSR1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV62204897; called by muse, mutect2, varscan2
- NR1I2 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV61977880, COSV61979089; called by muse, mutect2, varscan2
- NRBP2 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs782670268, COSV59918747; called by muse, mutect2, varscan2
- NRIP2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); catalogued as rs1310090785, COSV99958024; called by muse, mutect2
- NRK | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV54595489, COSV54602014; called by muse, mutect2, varscan2
- NRXN3 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs780219523, COSV73586282; called by muse, mutect2, varscan2
- NSUN6 | c.1377dup p.I460Yfs*64 | Frame Shift Ins (INS) | VAF 34/142 reads (24%) | catalogued as rs768858112; called by mutect2, varscan2
- NT5C1B | c.683G>A p.R228Q (on ENST00000359846 / NM_001199086.2; = p.R168Q on NM_033253.4) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs150624428, COSV58397679; called by muse, mutect2, varscan2
- NTAQ1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs764186305, COSV54875409; called by muse, mutect2, varscan2
- NTMT1 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs779632244, COSV52965533; called by muse, mutect2, varscan2
- NUFIP2 | c.1753A>G p.T585A | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56604945; called by muse, mutect2, varscan2
- NUP88 | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV99336374; called by muse, mutect2, varscan2
- OGT | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); catalogued as COSV65481929; called by muse, mutect2, varscan2
- OLFM2 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs765662180, COSV53428450; called by muse, mutect2, varscan2
- OLR1 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58872230; called by muse, mutect2, varscan2
- OMD | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178854329, COSV65020371; called by muse, mutect2, varscan2
- OPRL1 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.546); catalogued as rs113199372; called by muse, mutect2, varscan2
- OR2D2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs574075868, COSV55057740; called by muse, mutect2, varscan2
- OR2Z1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781783013, COSV60692925; called by muse, mutect2
- OR4D1 | c.548A>G p.Q183R | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV52125608; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR5B2 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.393); catalogued as rs199556711; called by muse, mutect2, varscan2
- OSBP | c.2080T>C p.Y694H | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as COSV55664398; called by muse, mutect2, varscan2
- P2RX4 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs767479436, COSV58742410, COSV58742770; called by muse, mutect2, varscan2
- PANX2 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs371220405; called by muse, mutect2, varscan2
- PAQR5 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142266731; called by muse, mutect2, varscan2
- PATL1 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV55691325; called by muse, mutect2, varscan2
- PCDH10 | c.679dup p.Q227Pfs*19 | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as rs762465989; called by mutect2, varscan2
- PCDH10 | c.2347A>G p.S783G | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV52099613, COSV52100712; called by muse, mutect2, varscan2
- PCDH10 | c.2915A>T p.N972I | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52099620; called by muse, mutect2, varscan2
- PCDH12 | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183621011, COSV51523081; called by muse, mutect2, varscan2
- PCDHA3 | c.1429G>A p.V477M | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV63544151; called by muse, mutect2, varscan2
- PCDHGA5 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs781279706, COSV53907148, COSV99541943; called by muse, mutect2, varscan2
- PCDHGA7 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV53992535; called by muse, mutect2, varscan2
- PCDHGA8 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.021); catalogued as COSV53892732; called by muse, mutect2, varscan2
- PCDHGB2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs1405122386, COSV53915529, COSV54061717; called by muse, mutect2, varscan2
- PCIF1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1275804988, COSV65026808; called by muse, mutect2, varscan2
- PCK1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs536299130, COSV60126231; called by muse, mutect2, varscan2
- PCSK6 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59343134; called by muse, mutect2, varscan2
- PDE3A | c.2209A>G p.N737D | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV62978294; called by muse, mutect2, varscan2
- PELP1 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.868); catalogued as COSV52590120, COSV52591907; called by muse, mutect2, varscan2
- PGK2 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs780494411, COSV59162756, COSV59165503; called by muse, mutect2, varscan2
- PIGN | c.1076G>T p.S359I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV62950783; called by muse, mutect2, varscan2
- PIK3R2 | c.1109+7del | Splice Region (DEL) | VAF 12/80 reads (15%) | catalogued as rs1392563018; called by mutect2, pindel, varscan2
- PIWIL1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745487305, COSV55347041, COSV55349697; called by muse, mutect2, varscan2
- PKDREJ | c.6226C>T p.R2076C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200552267, COSV53550734; called by muse, mutect2
- PKDREJ | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1304020096, COSV53551148; called by muse, mutect2
- PKP1 | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55823582, COSV99825168; called by muse, mutect2, varscan2
- PLAAT4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs770983321, COSV55373787; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 55/200 reads (28%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCXD2 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV67341371; called by muse, mutect2
- PLD2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1397763227, COSV54007885; called by muse, mutect2, varscan2
- PLEC | c.9563C>T p.S3188F (on ENST00000322810 / NM_201380.4; = p.S3078F on NM_000445.5) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as COSV59667152; called by muse, mutect2, varscan2
- PLEKHA2 | c.771T>G p.S257= | Splice Region (SNP) | VAF 34/191 reads (18%) | catalogued as COSV66243162; called by muse, mutect2, varscan2
- PLG | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.012); catalogued as COSV51984766; called by muse, mutect2, varscan2
- PLPP7 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs764693403, COSV64836137; called by muse, mutect2, varscan2
- PLPPR4 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV64564397; called by muse, mutect2
- PLXNA1 | c.3097G>A p.A1033T | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs753534974, COSV52530155; called by muse, mutect2
- PLXNB2 | c.694T>G p.F232V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV63783357; called by muse, mutect2, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as COSV64722654; called by mutect2, pindel, varscan2
- POLR2A | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59494229; called by muse, mutect2, varscan2
- POU3F3 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV63722153; called by muse, mutect2
- POU3F4 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV64538037; called by muse, mutect2, varscan2
- PRADC1 | c.444C>T p.D148= | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as rs538688575, COSV57820347; called by muse, mutect2, varscan2
- PRDM15 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.937); catalogued as rs760945193, COSV54156335; called by muse, mutect2, varscan2
- PRIM1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.042); catalogued as rs201428535, COSV57717575; called by muse, mutect2, varscan2
- PRKD2 | c.2597A>G p.H866R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.037); catalogued as rs1365976163, COSV52188409; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR16 | c.830del p.P277Lfs*20 (on ENST00000407149 / NM_001300783.2; = p.P254Lfs*20 on NM_016644.2) | Frame Shift Del (DEL) | VAF 10/71 reads (14%) | catalogued as COSV65401020; called by mutect2, pindel, varscan2
- PRRC2C | c.1885G>A p.V629I (on ENST00000367742; = p.V627I on NM_015172.4) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs759304251, COSV58903606; called by muse, mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs771809480; called by mutect2, pindel, varscan2
- PSD2 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); catalogued as COSV51205086; called by muse, mutect2, varscan2
- PSMB1 | c.127A>T p.I43F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV51531416; called by muse, mutect2, varscan2
- PTBP1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as rs770262479, COSV62458821; called by muse, mutect2, varscan2
- PTCH2 | c.2372-2A>G p.X791_splice | Splice Site (SNP) | VAF 29/125 reads (23%) | catalogued as rs982890242, COSV64712390; called by muse, mutect2, varscan2
- PTH2R | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs753279962, COSV55915312; called by muse, mutect2, varscan2
- PTHLH | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 17/128 reads (13%) | catalogued as COSV52368679; called by muse, mutect2, varscan2
- PTK2B | c.2709del p.E904Rfs*7 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs869044240; called by mutect2, pindel, varscan2
- PTPN14 | c.3122C>G p.T1041S | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as COSV65286079; called by muse, mutect2, varscan2
- PTPN23 | c.3343G>A p.A1115T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs763104053, COSV55546400; called by muse, mutect2, varscan2
- PTPRM | c.3085A>G p.T1029A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59856983; called by muse, mutect2, varscan2
- PTPRS | c.3550-1G>T p.X1184_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV53629439; called by muse, mutect2, varscan2
- PTX4 | c.367C>T p.R123W (on ENST00000447419 / NM_001328608.2; = p.R118W on NM_001013658.1) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV53518245, COSV53520390; called by muse, mutect2, varscan2
- PYHIN1 | c.1342A>G p.S448G | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63723280; called by muse, mutect2
- RAB11FIP1 | c.1344G>T p.K448N | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV54762269; called by muse, mutect2, varscan2
- RAB33A | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57062731; called by muse, mutect2
- RAD54L2 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs754168484, COSV56580271; called by muse, mutect2, varscan2
- RARS2 | c.963_964del p.Y322Cfs*16 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | catalogued as rs773838753; called by pindel, varscan2
- RASD2 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1442019893, COSV53352044; called by muse, mutect2, varscan2
- RBCK1 | c.1121C>A p.P374Q (on ENST00000356286 / NM_031229.4; = p.P332Q on NM_006462.6) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV62292806; called by muse, mutect2, varscan2
- RBM15 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV63923942; called by muse, mutect2, varscan2
- RBM23 | c.368G>A p.R123H (on ENST00000359890 / NM_001077351.2; = p.R107H on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as rs767422029, COSV57128396; called by muse, mutect2, varscan2
- RECQL4 | c.1579A>G p.T527A | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as rs760080894, COSV52881043; called by muse, mutect2, varscan2
- RET | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs774092678, COSV60701999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REV3L | c.7834G>A p.V2612I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375272662; called by muse, mutect2, varscan2
- RHBDL1 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV54804530; called by muse, mutect2, varscan2
- RIMKLB | c.593A>T p.E198V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as COSV55238937; called by muse, mutect2, varscan2
- RIMS4 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs901042513, COSV65720273; called by muse, mutect2, varscan2
- RMND5A | c.777G>A p.W259* | Nonsense Mutation (SNP) | VAF 6/110 reads (5%) | catalogued as COSV52154726; called by muse, mutect2
- RNF126 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139851549; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs752898741; called by mutect2, varscan2
- RPRML | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59262869; called by muse, mutect2, varscan2
- RPS3A | c.542T>C p.L181S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56839524; called by muse, mutect2
- RPS5 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52191413; called by muse, mutect2, varscan2
- RTKN | c.1666C>T p.R556C (on ENST00000272430 / NM_001015055.2; = p.R543C on NM_033046.2) | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs1253780029, COSV51961727; called by muse, mutect2, varscan2
- RTN2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1158609094, COSV55593774; called by muse, mutect2, varscan2
- RUNDC3B | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs1279340526, COSV55957481; called by muse, mutect2, varscan2
- RUSC1 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); catalogued as COSV52741538; called by muse, mutect2, varscan2
- RYR1 | c.1823_1824dup p.N609Vfs*58 | Frame Shift Ins (INS) | VAF 50/264 reads (19%) | catalogued as rs1479361437; called by mutect2, varscan2
- RYR1 | c.3098G>A p.S1033N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV62104084; called by muse, mutect2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs749201569; called by mutect2, varscan2
- SCAF4 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV54590052; called by muse, mutect2, varscan2
- SCN2B | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV54051444; called by muse, mutect2, varscan2
- SCRIB | c.3754G>A p.E1252K | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs769393665, COSV57590578; called by muse, mutect2, varscan2
- SCUBE3 | c.1852C>T p.R618* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | catalogued as COSV51458847; called by muse, mutect2, varscan2
- SDC4 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as rs901163167, COSV65594977; called by muse, mutect2, varscan2
- SDK2 | c.1282del p.A428Rfs*63 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as COSV66189239; called by mutect2, pindel, varscan2
- SERINC4 | c.939_940del p.R313Sfs*17 | Frame Shift Del (DEL) | VAF 42/234 reads (18%) | catalogued as rs752608640; called by pindel, varscan2
- SETD5 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1257894154, COSV56714784; called by muse, mutect2, varscan2
- SFI1 | c.3295G>T p.A1099S (on ENST00000400288 / NM_001007467.3; = p.A1068S on NM_014775.4) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV56718301; called by muse, mutect2
- SFRP2 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 24/83 reads (29%) | catalogued as COSV56838150, COSV56838365; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs747473028; called by mutect2, varscan2
- SH2D1B | c.135-1G>T p.X45_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV63392511; called by muse, mutect2, varscan2
- SHOX2 | c.539C>T p.S180L (on ENST00000441443 / NM_006884.3; = p.S204L on NM_003030.4) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101273727, COSV67463954, COSV67464313; called by muse, mutect2, varscan2
- SIAE | c.544+2T>C p.X182_splice | Splice Site (SNP) | VAF 42/208 reads (20%) | catalogued as COSV55015168; called by muse, mutect2, varscan2
- SIPA1L2 | c.1607G>T p.R536M | Missense Mutation (SNP) | VAF 89/396 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53395239; called by muse, mutect2, varscan2
- SLC12A9 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs761904558, COSV51935499; called by muse, mutect2, varscan2
- SLC16A11 | c.82del p.Q28Sfs*21 (on ENST00000308009; = p.Q4Sfs*21 on NM_153357.3) | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs139324407; called by mutect2, pindel
- SLC17A4 | c.1165A>G p.R389G | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV64956792; called by muse, mutect2, varscan2
- SLC19A2 | c.566G>A p.S189N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV52548313; called by muse, mutect2, varscan2
- SLC25A19 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57468142; called by muse, mutect2, varscan2
- SLC2A5 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.11); catalogued as COSV66237503; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC46A3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759574136, COSV57180509; called by muse, mutect2, varscan2
- SLC5A9 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345828939, COSV52584787; called by muse, mutect2, varscan2
- SLC6A1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs910130675, COSV55117217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A18 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV57253042; called by muse, mutect2, varscan2
- SLC6A19 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs200657233, COSV58673018; called by muse, mutect2, varscan2
- SLC6A3 | c.1126A>G p.S376G | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV54367051; called by muse, mutect2, varscan2
- SLC8A1 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.254); catalogued as COSV60489882; called by muse, mutect2, varscan2
- SLC9A2 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV52135089, COSV99296855; called by muse, mutect2, varscan2
- SLFN11 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs369831357; called by muse, mutect2, varscan2
- SLTM | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.475); catalogued as rs766854980, COSV51055941; called by muse, mutect2, varscan2
- SLU7 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as rs1001389279, COSV51789140; called by muse, mutect2, varscan2
- SMC1B | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.758); catalogued as rs370524975; called by muse, mutect2, varscan2
- SMCR8 | c.1307A>C p.E436A | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV58179516; called by muse, mutect2, varscan2
- SMR3A | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV56950689; called by muse, mutect2, varscan2
- SNAPC4 | c.4399C>T p.R1467W | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs144652680; called by muse, mutect2, varscan2
- SNF8 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.935); catalogued as rs763236773, COSV51727337; called by muse, mutect2, varscan2
- SORD | c.892T>C p.F298L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV51044254; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs746109620; called by mutect2, varscan2
- SP4 | c.1307T>C p.I436T | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV56025009; called by muse, mutect2, varscan2
- SPAG9 | c.811G>A p.G271R (on ENST00000262013 / NM_001130528.3; = p.G257R on NM_003971.6) | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs1426743677, COSV56239869, COSV56241511; called by muse, mutect2, varscan2
- SPANXN3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as COSV65140625; called by muse, mutect2, varscan2
- SPATA5 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56780438; called by muse, mutect2, varscan2
- SPECC1 | c.2210A>T p.D737V | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54962538; called by muse, mutect2, varscan2
- SPECC1L | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199712268, COSV58660085; called by muse, mutect2, varscan2
- SPG11 | c.7054T>C p.Y2352H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs149711747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SREK1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV52334171; called by muse, mutect2, varscan2
- SREK1IP1 | c.381del p.K129Nfs*29 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as rs1470980144, COSV72486131; called by mutect2, varscan2
- SRSF12 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs757624112, COSV71683737; called by muse, mutect2, varscan2
- SSH1 | c.3131C>T p.S1044L | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs375673898; called by muse, mutect2, varscan2
- SSX2IP | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as rs868158262, COSV60553772; called by muse, mutect2, varscan2
- ST6GAL2 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 54/212 reads (25%) | catalogued as COSV64530252; called by muse, mutect2, varscan2
- STAB1 | c.4951C>T p.R1651W | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV58740388; called by muse, mutect2, varscan2
- STAB2 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV66343312; called by muse, mutect2, varscan2
- STAT1 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as rs371982540; called by muse, mutect2, varscan2
- STK17A | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.798); catalogued as COSV60046268, COSV60048044; called by muse, mutect2, varscan2
- STOML1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs116083516, COSV57551105; called by muse, mutect2, varscan2
- STOML2 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); catalogued as rs775482860, COSV59717023; called by muse, mutect2, varscan2
- STOML3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903262432, COSV65511362; called by muse, mutect2, varscan2
- SUMF2 | c.250G>A p.D84N (on ENST00000652303; = p.D65N on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs770460250, COSV51906886; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SWAP70 | c.305del p.N102Tfs*31 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | catalogued as rs749995893; called by mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | catalogued as rs753462162; called by mutect2, varscan2
- SYNE1 | c.8306A>C p.K2769T (on ENST00000367255 / NM_182961.4; = p.K2776T on NM_033071.3) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54911160; called by muse, mutect2, varscan2
- SYNE1 | c.5587C>T p.R1863W (on ENST00000367255 / NM_182961.4; = p.R1870W on NM_033071.3) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs769949513, COSV54992747; called by muse, mutect2, varscan2
- SYTL4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs760447949, COSV52167221; called by muse, mutect2, varscan2
- TAF1C | c.1361del p.P454Lfs*14 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs749363736; called by mutect2, pindel, varscan2
- TAL1 | c.86dup p.H30Afs*146 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as rs750167290; called by mutect2, varscan2
- TANC2 | c.4556del p.P1519Lfs*33 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV101267456, COSV67333336; called by mutect2, pindel, varscan2
- TASOR2 | c.6056C>A p.P2019H | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100050059; called by muse, mutect2
- TBC1D2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs140114775, COSV59787026; called by muse, mutect2, varscan2
- TBC1D4 | c.311del p.G104Afs*39 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs749748051; called by mutect2, pindel
- TBC1D9B | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1362607242, COSV62283118; called by muse, mutect2, varscan2
- TCEAL5 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV65503429; called by muse, varscan2
- TCEAL9 | c.148A>G p.I50V | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.09); catalogued as COSV65489086; called by muse, mutect2, varscan2
- TDRD3 | c.1723del p.A575Qfs*11 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | catalogued as COSV52158105; called by mutect2, pindel, varscan2
- TDRKH | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1231192102, COSV64316549; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 65/270 reads (24%) | catalogued as rs763321097; called by mutect2, varscan2
- TECR | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs775199162, COSV53108648; called by muse, mutect2, varscan2
- TEK | c.3047C>T p.T1016I | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233910639, COSV66231057; called by muse, mutect2, varscan2
- TET1 | c.843G>T p.K281N | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV65387204, COSV65389773; called by muse, varscan2
- TEX12 | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54784557; called by muse, mutect2, varscan2
- TEX14 | c.2947G>C p.E983Q (on ENST00000240361 / NM_001201457.2; = p.E977Q on NM_031272.5) | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV53622140; called by muse, mutect2, varscan2
- THOP1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs373946615; called by muse, mutect2, varscan2
- TIAM1 | c.2651C>A p.A884D | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54563777; called by muse, mutect2, varscan2
- TLR9 | c.2537G>A p.C846Y | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62347712; called by muse, mutect2, varscan2
- TMCO6 | c.488C>G p.S163* | Nonsense Mutation (SNP) | VAF 37/166 reads (22%) | catalogued as COSV52800584; called by muse, mutect2, varscan2
- TMEM121B | c.899dup p.G301Rfs*304 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | catalogued as rs1555876147; called by pindel, varscan2
- TMEM184B | c.695T>C p.F232S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62673350; called by muse, mutect2, varscan2
- TMOD4 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.751); catalogued as COSV54861509; called by muse, mutect2, varscan2
- TNFRSF21 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as rs142206681, COSV57283833; called by muse, mutect2, varscan2
- TNFSF14 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs202048657, COSV55591291; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNS3 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV60790737; called by muse, mutect2, varscan2
- TOGARAM1 | c.3608del p.N1203Ifs*6 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | catalogued as rs1188837380, COSV63890677; called by pindel, varscan2
- TOP1MT | c.1780A>G p.M594V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.345); catalogued as COSV61318980; called by muse, mutect2, varscan2
- TPCN1 | c.2432G>A p.R811H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs566314380, COSV99176657; called by muse, mutect2, varscan2
- TPR | c.3772C>T p.Q1258* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV66603278; called by muse, mutect2, varscan2
- TRAF1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs547890013, COSV65868969; called by muse, mutect2, varscan2
- TRANK1 | c.6125G>T p.G2042V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV57157942; called by muse, mutect2, varscan2
- TRAPPC11 | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.973); catalogued as rs374203755; called by muse, mutect2, varscan2
- TRIM24 | c.3137G>A p.R1046H (on ENST00000343526 / NM_015905.3; = p.R1012H on NM_003852.4) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as rs560006714, COSV58974214; called by muse, mutect2, varscan2
- TRIM26 | c.845del p.K282Rfs*16 | Frame Shift Del (DEL) | VAF 28/125 reads (22%) | catalogued as rs1271434984; called by mutect2, varscan2
- TRMT10A | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV56745702; called by muse, mutect2, varscan2
- TRPA1 | c.2815G>T p.A939S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as COSV51568401; called by muse, mutect2, varscan2
- TRPA1 | c.2390G>T p.R797M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.501); catalogued as rs200192163, COSV51557200, COSV51560243; called by muse, mutect2, varscan2
- TRPM8 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as rs371608612; called by muse, mutect2
- TTK | c.2564del p.G855Efs*38 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as COSV57886369; called by pindel, varscan2
- TTLL1 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs1248062666, COSV56739961; called by muse, mutect2
- TTN | c.42458T>C p.V14153A (on ENST00000591111; = p.V6729A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | PolyPhen benign (0.082); catalogued as COSV59971434, COSV60208545; called by muse, mutect2, varscan2
- TUBB6 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.277); catalogued as rs751476032, COSV52316295; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs760251146; called by mutect2, varscan2
- TXLNG | c.218G>A p.G73D | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV66330223; called by muse, mutect2
- UBB | c.570dup p.D191Rfs*20 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | catalogued as rs750712511; called by mutect2, varscan2
- UBE2J1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs750694699, COSV70561973; called by muse, mutect2, varscan2
- UBR2 | c.4169del p.C1390Lfs*20 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as COSV65749968; called by mutect2, pindel, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 22/140 reads (16%) | catalogued as rs763652408; called by mutect2, varscan2
- UBXN11 | c.1075C>A p.Q359K (on ENST00000374221 / NM_183008.2; = p.Q326K on NM_145345.2) | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV54626033; called by muse, mutect2, varscan2
- UBXN6 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758984301, COSV56674768; called by mutect2, varscan2
- UCK1 | c.269A>T p.D90V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64734963; called by muse, mutect2, varscan2
- UCK1 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64735832; called by muse, mutect2, varscan2
- UCN3 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1290858866, COSV66824153; called by muse, mutect2, varscan2
- UGT1A4 | c.517del p.W173Gfs*8 | Frame Shift Del (DEL) | VAF 33/191 reads (17%) | catalogued as rs780658532; called by mutect2, pindel, varscan2
- ULK1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs751254383, COSV58856799; called by muse, mutect2, varscan2
- UNC5C | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.393); catalogued as COSV71661243; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs767420916; called by mutect2, varscan2
- VAX2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150176075; called by muse, mutect2, varscan2
- VPS13A | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs781120866, COSV62434233; called by muse, mutect2, varscan2
- VPS51 | c.1550del p.G517Vfs*42 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as COSV99659530; called by mutect2, pindel, varscan2
- VWA2 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs746390207, COSV53909153; called by muse, mutect2, varscan2
- VWA3B | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1264488515, COSV68241042, COSV68244910; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as rs756173793; called by mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | catalogued as rs762079039; called by mutect2, varscan2
- WNT1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs747833576, COSV53296422; called by muse, mutect2, varscan2
- WNT2B | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV56675918; called by muse, mutect2, varscan2
- WRN | c.2591G>A p.C864Y | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53304046; called by muse, mutect2
- WWC1 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54655082; called by muse, mutect2, varscan2
- XKR6 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52009013; called by muse, mutect2, varscan2
- XPNPEP2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs780025939, COSV64368075; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | catalogued as rs762052135; called by mutect2, varscan2
- XRRA1 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs776334769, COSV55131646; called by mutect2, varscan2
- YTHDF1 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64833519; called by muse, mutect2, varscan2
- YY1AP1 | c.1484G>A p.R495Q (on ENST00000295566 / NM_139118.2; = p.R438Q on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as rs749346586, COSV55123503; called by muse, mutect2, varscan2
- ZBED8 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750602510, COSV68824720; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 9/29 reads (31%) | catalogued as COSV59691020; called by mutect2, pindel, varscan2
- ZBTB9 | c.881A>C p.E294A | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV101221847, COSV67702290; called by muse, mutect2, varscan2
- ZC3H13 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1377400470, COSV54447865; called by muse, mutect2, varscan2
- ZC3H3 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 18/108 reads (17%) | catalogued as COSV52792578; called by muse, mutect2, varscan2
- ZCCHC14 | c.2419G>A p.A807T (on ENST00000268616; = p.A944T on NM_015144.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs1309191284, COSV51885996; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFYVE1 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV59612078; called by muse, mutect2, varscan2
- ZHX3 | c.2168G>A p.S723N | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as COSV58386393; called by muse, mutect2, varscan2
- ZIC1 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51556088; called by muse, mutect2, varscan2
- ZMYM2 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774135253, COSV67033994; called by muse, varscan2
- ZNF132 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs775440535, COSV54235599; called by muse, mutect2, varscan2
- ZNF197 | c.1608A>C p.K536N | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760501026, COSV60361268; called by muse, mutect2, varscan2
- ZNF221 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs541240926, COSV52110397; called by muse, mutect2, varscan2
- ZNF318 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs866272609, COSV58929874; called by muse, mutect2, varscan2
- ZNF330 | c.14del p.K5Rfs*18 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs770975379; called by mutect2, varscan2
- ZNF460 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1316815715, COSV64416066; called by muse, mutect2, varscan2
- ZNF462 | c.3691G>A p.A1231T | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52931405; called by muse, varscan2
- ZNF479 | c.381del p.K127Nfs*74 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | catalogued as rs782331095; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF519 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs576575185, COSV73913509; called by muse, mutect2, varscan2
- ZNF568 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as rs565321465, COSV61741373; called by muse, mutect2, varscan2
- ZNF608 | c.3479C>T p.P1160L | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs774125321, COSV60435410; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 44/178 reads (25%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF618 | c.2219C>T p.T740M (on ENST00000374126 / NM_001318042.2; = p.T647M on NM_133374.2) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs375702223; called by muse, mutect2, varscan2
- ZNF628 | c.2591C>T p.T864M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV52701189; called by muse, mutect2, varscan2
- ZNF668 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs867888998, COSV56216989; called by muse, mutect2, varscan2
- ZNF681 | c.1773A>C p.Q591H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV68075043; called by muse, mutect2, varscan2
- ZNF691 | c.634G>A p.A212T (on ENST00000372502; = p.A181T on NM_015911.3) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV65289495; called by muse, mutect2, varscan2
- ZNF696 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as COSV57525382; called by muse, mutect2
- ZNF770 | c.2066C>T p.S689L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV62544659; called by muse, mutect2, varscan2
- ZNF777 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV56099122, COSV99924903; called by muse, mutect2, varscan2
- ZNF786 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs1440701010, COSV60275000; called by muse, mutect2, varscan2
- ZNF786 | c.1570C>T p.L524F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420860597, COSV100302698; called by muse, mutect2, varscan2
- ZNF786 | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV100302700; called by muse, mutect2, varscan2
- ZNF8 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 69/293 reads (24%) | catalogued as rs199700427, COSV52188726; called by muse, mutect2, varscan2
- ZNF827 | c.2012A>C p.K671T | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs771073905, COSV65229786; called by muse, mutect2, varscan2
- AASDH | c.1233del p.D413Mfs*4 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by pindel, varscan2
- ACP1 | c.167dup p.D57* | Frame Shift Ins (INS) | VAF 22/98 reads (22%) | called by pindel, varscan2
- AGL | c.617dup p.E207Gfs*9 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- AP2M1 | c.671dup p.Q225Afs*7 | Frame Shift Ins (INS) | VAF 39/211 reads (18%) | called by mutect2, pindel, varscan2
- APEH | c.271del p.E91Nfs*3 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- ART5 | c.678_679dup p.H227Pfs*19 | Frame Shift Ins (INS) | VAF 32/143 reads (22%) | called by mutect2, varscan2
- ASCL4 | c.109del p.L37Sfs*53 | Frame Shift Del (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel
- ASIC3 | c.839del p.G280Afs*8 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2625del p.V876Cfs*59 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, varscan2
- ATG9B | c.189del p.S64Pfs*42 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- BAG4 | c.1365del p.G456Dfs*6 | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, varscan2
- BCL6B | c.1434del p.*480Sfs*2 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- BPTF | c.9016_9018del p.Y3006del | In Frame Del (DEL) | VAF 20/116 reads (17%) | called by pindel, varscan2
- BSN | c.1316dup p.H440Afs*44 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- C1QL3 | c.581dup p.N194Kfs*7 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- CAMSAP3 | c.1313dup p.R439Afs*17 | Frame Shift Ins (INS) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- CAMTA2 | c.1179dup p.Q394Afs*54 | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- CAST | c.387del p.E130Kfs*5 (on ENST00000341926; = p.E213Kfs*5 on NM_001750.7 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- CLCN3 | c.1939_1941del p.E647del | In Frame Del (DEL) | VAF 26/132 reads (20%) | called by pindel, varscan2
- CLDN6 | c.567del p.S190Pfs*70 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- CLHC1 | c.690del p.K230Nfs*11 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, pindel, varscan2
- CLMN | c.2594del p.K865Rfs*10 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | called by mutect2, pindel, varscan2
- CXorf65 | c.158del p.F53Sfs*2 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- DAPK3 | c.222del p.N75Tfs*37 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by pindel, varscan2
- DGKH | c.1008dup p.V337Cfs*4 | Frame Shift Ins (INS) | VAF 11/115 reads (10%) | called by mutect2, pindel
- DYSF | c.3343del p.A1115Pfs*5 | Frame Shift Del (DEL) | VAF 33/139 reads (24%) | called by mutect2, pindel, varscan2
- EEF2 | c.775_777del p.K259del | In Frame Del (DEL) | VAF 10/66 reads (15%) | called by pindel, varscan2
- EGLN1 | c.1224del p.G409Vfs*2 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- ENTPD2 | c.611del p.G204Vfs*171 | Frame Shift Del (DEL) | VAF 26/138 reads (19%) | called by mutect2, pindel, varscan2
- EPG5 | c.5704del p.Y1902Ifs*26 | Frame Shift Del (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- ERBB4 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 25/117 reads (21%) | called by mutect2, pindel, varscan2
- FA2H | c.729del p.S244Afs*37 | Frame Shift Del (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- FAM135B | c.3312del p.E1105Nfs*2 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- FANCB | c.1865del p.L622* | Frame Shift Del (DEL) | VAF 65/237 reads (27%) | called by mutect2, varscan2
- FBXW7 | c.1417dup p.R473Kfs*4 (on ENST00000281708 / NM_001349798.2; = p.R393Kfs*4 on NM_018315.5) | Frame Shift Ins (INS) | VAF 49/206 reads (24%) | called by mutect2, pindel, varscan2
- FCGBP | c.11291_11293del p.D3764del | In Frame Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- FOXD4L6 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- FSIP2 | c.19608del p.I6537Ffs*5 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- FUT11 | c.1384del p.E462Kfs*6 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | called by mutect2, pindel, varscan2
- GATB | c.300del p.F100Lfs*17 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, varscan2
- GLIS1 | c.323dup p.L109Sfs*23 | Frame Shift Ins (INS) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- GLRX2 | c.254del p.K85Sfs*6 (on ENST00000367439 / NM_197962.3; = p.K86Sfs*6 on NM_016066.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- GSPT2 | c.1148del p.K383Rfs*11 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | called by mutect2, pindel, varscan2
- GUCA2B | c.166del p.R56Afs*37 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- H2BC14 | c.39del p.G14Afs*33 | Frame Shift Del (DEL) | VAF 29/140 reads (21%) | called by mutect2, pindel, varscan2
304 further variants in this file (67 protein-altering or splice-affecting, 222 silent, 15 other) are not listed here.
